Somatic mutation profile of cancer-model specimen HCM-BROD-0762-C49-85B (Adherent Cell Line, passage 19; aliquot HCM-BROD-0762-C49-85B-01D-A87L-36), derived from the primary tumor of HCMI case HCM-BROD-0762-C49, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Abdominal fibromatosis; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 15.9 years (5,799 days).
Specimen HCM-BROD-0762-C49-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 19.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e4eac92f-3e51-427f-80ab-b94943208582.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0762-C49-11A (Solid Tissue Normal), aliquot HCM-BROD-0762-C49-11A-01D-A87L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6eb0011d-a2a7-4576-9ee0-453632f3a9f9

The open-access MAF lists 29 somatic variants for this specimen: 20 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 8, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HYDIN | c.11431C>A p.R3811S | Missense Mutation (SNP) | VAF 20/320 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.091); catalogued as COSV66637901; called by muse, mutect2
- NPFFR2 | c.1024G>A p.G342R | Missense Mutation (SNP) | VAF 46/554 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.82); catalogued as COSV58155655; called by muse, mutect2
- SATB1 | c.177C>G p.H59Q | Missense Mutation (SNP) | VAF 45/310 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.133); catalogued as COSV100112933; called by muse, mutect2, varscan2
- SYNE1 | c.25928A>G p.K8643R (on ENST00000367255 / NM_182961.4; = p.K8595R on NM_033071.3) | Missense Mutation (SNP) | VAF 22/586 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.174); catalogued as rs1311607461; called by muse, mutect2
- TENT5D | c.895C>A p.L299I | Missense Mutation (SNP) | VAF 72/649 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100382541; called by muse, mutect2, varscan2
- UBE2J1 | c.644C>G p.P215R | Missense Mutation (SNP) | VAF 118/294 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs112892732; called by muse, mutect2
- ADGRL2 | c.2453C>G p.T818R (on ENST00000370717 / NM_001366005.1; = p.T805R on NM_012302.4) | Missense Mutation (SNP) | VAF 37/513 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CABLES2 | c.1033A>C p.N345H | Missense Mutation (SNP) | VAF 16/569 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CD93 | c.706C>A p.H236N | Missense Mutation (SNP) | VAF 107/502 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAM160A2 | c.625C>A p.R209S | Missense Mutation (SNP) | VAF 249/539 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- ISLR2 | c.2036A>C p.E679A | Missense Mutation (SNP) | VAF 26/622 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.091); called by muse, mutect2
- MDN1 | c.3009C>G p.H1003Q | Missense Mutation (SNP) | VAF 26/525 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.024); called by muse, mutect2
- MYH8 | c.2155G>T p.G719C | Missense Mutation (SNP) | VAF 98/222 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- RPS6KA3 | c.121C>A p.Q41K | Missense Mutation (SNP) | VAF 118/265 reads (45%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- SAMD4A | c.1074C>G p.C358W | Missense Mutation (SNP) | VAF 55/356 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- SNX8 | c.503A>C p.D168A | Missense Mutation (SNP) | VAF 117/369 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by mutect2, varscan2
- SPTLC3 | c.673A>G p.M225V | Missense Mutation (SNP) | VAF 18/346 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.021); called by muse, mutect2
- STK36 | c.2002G>A p.A668T | Missense Mutation (SNP) | VAF 18/359 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2
- UBE2J1 | c.642A>G p.I214M | Missense Mutation (SNP) | VAF 122/298 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2
- ZC3H13 | c.2140G>C p.E714Q | Missense Mutation (SNP) | VAF 48/610 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.478); called by muse, mutect2
- C12orf40 | c.399C>T p.D133= | Silent (SNP) | VAF 90/311 reads (29%) | catalogued as rs1421959445; called by muse, mutect2, varscan2
- C17orf97 | c.603C>A p.A201= | Silent (SNP) | VAF 18/624 reads (3%) | called by muse, mutect2
- C2orf81 | c.1563G>T p.P521= | Silent (SNP) | VAF 26/646 reads (4%) | catalogued as rs1473208486; called by muse, mutect2
- DTHD1 | c.1605G>T p.V535= (on ENST00000456874; = p.V370= on NM_001136536.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/586 reads (5%) | catalogued as COSV62629654; called by muse, mutect2
- HDAC7 | c.1347G>A p.L449= (on ENST00000427332; = p.L488= on NM_015401.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/500 reads (4%) | catalogued as rs1324407095; called by muse, mutect2
- MINDY4B | c.762G>A p.G254= | Silent (SNP) | VAF 14/464 reads (3%) | called by muse, mutect2
- SLC25A36 | c.642A>G p.E214= | Silent (SNP) | VAF 12/381 reads (3%) | called by muse, mutect2
- WNT9B | c.690G>A p.P230= | Silent (SNP) | VAF 44/706 reads (6%) | catalogued as rs762955367, COSV51517656; called by muse, mutect2
- RNU6-784P | chr4:70704985 G>C | 5'Flank (SNP) | VAF 40/578 reads (7%) | called by muse, mutect2
